Surgical pathology report (de-identified scan), TCGA case TCGA-CD-8527, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-8527-01A (Primary Tumor).

[page 1 of 6]
Name of Physician or Study Coordinator

Signature

Clinical Information

HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain, nausea and vomit.

Symptoms: weight loss

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)		
				/	/	To / /
				/	/	To / /
				/	/	To / /
				/	/	To / /
				/	/	To / /
				/	/	To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY	
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☒ Post-menopausal	Date of First Menses Don't remember Date of Last Menses Don't remember
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other:	☐ Hormone Replacement Therapy:

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA				
Test	Result	Test	Result	Date
HIV	☒ Negative ☐ Positive:	EA	☐ Negative ☐ Positive:	
Hep B	☒ Negative ☐ Positive:	15-3	☐ Negative ☐ Positive:	
Hep C	☒ Negative ☐ Positive:	CA 19-9	☐ Negative ☐ Positive:	
AFP	☐ Negative ☐ Positive:	PSA	☐ Negative ☐ Positive:	
Other:	☐ Negative ☐ Positive:	Other:	☐ Negative ☐ Positive:	
B/T Cell Markers:				

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy ✓	ulceration at the pylorus	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	
T2 N1 M0	Stage: II

Treatment Information

SURGICAL TREATMENT		
Procedure		
Extended gastrectomy		
Primary Tumor		
Organ	Detailed Location	Size
stomach tumor	gastric antrum	6 x 5 x 3 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T2 N1 M0		Stage: II

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

SPECIMEN TYPE (# of samples provided)

Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION

Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach tumor	6 x 5 x 3 cm	Anterior	7 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N 1 M 0		Stage: II	

Notes:

2 cassettes stomach nodes in nitrogen
(M₁, M₂ positive)

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution					Structural Pattern						
	+	-							+	-	
Diffuse		☒			Streaming						
Mosaic					Storiform						
Necrosis					Fibrosis						
Lymphocytic Infiltration		☒			Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						

Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell				Glandular cell		☒		Round Cell				Large Cell			
Spindle Cell				Cell Stratification				Fibroblast				Small Cell			
Keratin				Secretion				Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pearl				Gland formation		☒		Myoblast				Plasma Cell			

Cellular Differentiation:				
		Well	Moderate	Poor
Nuclear Appearance				
Nuclear Atypia:		0	I	II
Aniso Nucleosis			☒	
Hyperchromatism				☒
Nucleolar Prominent				☒
Multinucleated Giant Cell				☒
Mitotic Activity				
Nuclear Grade:				

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

[page 6 of 6]
Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		X	Streaming		
Mosaic	X		Storiform		
Necrosis		X	Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion		X	Cystic Degeneration		
Clusterized	X		Bleeding		
Alveolar Formation		X	Myxoid Change		
Indian File		X	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		
Otherwise Specified: D1 70%, D2 70%, D3 70%, D4 80%											

2. Cellular Differentiation:

Well	Moderately	Poor
	X	

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			X	
Hyperchromatism			X	
Nucleolar Prominent			X	
Multinucleated Giant Cell			X	
Mitotic Activity			X	
Nuclear Grade				

Histological Diagnosis: Stenocaprine, 105 (Intestinal), G2

Source: NCI Genomic Data Commons file 881376f4-93f3-42cb-ba60-ed8b4906aa35 (TCGA-CD-8527.0BF5D180-3BE0-47D0-ACAA-E3075BC63FCE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).